Somatic mutation profile of tumor specimen TARGET-10-PARDEP-09A (aliquot TARGET-10-PARDEP-09A-01D) from TARGET case TARGET-10-PARDEP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.8 years (4,673 days).
Specimen TARGET-10-PARDEP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1adf4929-4590-4f91-819b-706003be57e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDEP-10A (Blood Derived Normal), aliquot TARGET-10-PARDEP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e316115-5ee5-4c6e-a04f-fc00cdb3255c

The open-access MAF lists 25 somatic variants for this specimen: 17 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 7, Nonsense Mutation 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADD2 | c.1933G>T p.E645* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as COSV100035346; called by muse, varscan2
- BRINP1 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 15/112 reads (13%) | catalogued as COSV99774274, COSV99775546; called by muse, mutect2, varscan2
- CACNA1C | c.6118G>A p.V2040I (on ENST00000399634 / NM_001167625.1; = p.V1969I on NM_000719.7) | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs748408098; ClinVar: likely benign; called by muse, mutect2, varscan2
- CTCF | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV50504119; called by mutect2, varscan2
- DEFB119 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.649); catalogued as rs150495779; called by mutect2, varscan2
- MED31 | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV51513779; called by muse, mutect2
- MEF2C | c.659G>T p.R220L | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100424495; called by muse, mutect2
- TCHHL1 | c.1952G>A p.G651E | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.5); PolyPhen benign (0.1); catalogued as COSV64286577; called by muse, mutect2, varscan2
- GAPVD1 | c.4410C>A p.F1470L (on ENST00000394104; = p.F1479L on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); called by muse, mutect2
- HECTD4 | c.5317G>T p.A1773S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LARS1 | c.2083G>T p.E695* (on ENST00000394434 / NM_020117.11; = p.E668* on NM_016460.3) | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | called by muse, varscan2
- MED12 | c.6494C>T p.T2165I | Missense Mutation (SNP) | VAF 79/87 reads (91%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MRPL1 | c.661C>A p.L221I | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.013); called by muse, mutect2
- MTHFD2 | c.239C>A p.A80E | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- NPFFR2 | c.219C>A p.S73R | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); called by muse, mutect2
- UBR4 | c.7219G>T p.A2407S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, varscan2
- ZNF134 | c.569C>A p.T190K | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2
- ADAM30 | c.2109G>T p.V703= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- BARX1 | c.84C>T p.S28= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs1313105735; called by muse, mutect2, varscan2
- CALHM5 | c.522C>A p.S174= | Silent (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- DNAH2 | c.5538C>A p.A1846= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- GABRR2 | c.624G>T p.L208= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV101298977, COSV68765066; called by mutect2, varscan2
- INSR | c.1695G>T p.L565= | Silent (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- PEPD | c.885C>T p.N295= | Silent (SNP) | VAF 57/175 reads (33%) | catalogued as rs771953603, COSV54890995; called by muse, mutect2, varscan2
- TTN | c.34354+581A>C | Intron (SNP) | VAF 80/96 reads (83%) | called by muse, mutect2, varscan2
